Surgical pathology report (de-identified scan), TCGA case TCGA-B3-3925, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B3-3925-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

A. Left renal mass

CLINICAL NOTES

PRE-OP DIAGNOSIS: Renal mass.

FROZEN SECTION DIAGNOSIS

FS - Renal cortical carcinoma, margins negative for tumor.

GROSS DESCRIPTION

A. Received fresh for frozen section and tissue procurement labeled "left renal mass". It consist of a partial nephrectomy with loosely attached perinephric fat. It consist of a rounded portion of renal cortical tissue the base of which measures 3.9 x 4 cm. No grossly evident tumor is present at the margin. This margin is inked black. On the surface of this specimen there is a protruding dome-shaped yellow tumor mass measuring 1.5 cm. above the surrounding renal surface. On section, this corresponds to a soft dull tan yellow tumor measuring 3.1 x 3 x 3.1 cm. On section it comes extremely close to the deep resection margin. Peripheral margins are grossly spared. The attached perinephric fat is without tumor nodules. A frozen section of the deep margin is performed. Samples are also taken for tissue procurement. Additional representative sections are submitted in 6 cassettes, following fixation.

MICROSCOPIC DESCRIPTION

Histologic type: Papillary renal cell carcinoma
Histologic grade (Fuhrman Nuclear Grade): 2
Primary tumor (pT): The tumor measures 3.1 cm. in maximum dimension and extends through the renal capsule and minimally into perirenal

[page 2 of 2]
MICROSCOPIC DESCRIPTION

fat, pT3a.
Margins of resection: All margins negative for tumor.
Regional lymph nodes (pN): Cannot be assessed.
Distant metastasis (pM): Cannot be assessed.
Vascular invasion: Negative.
Non-neoplastic kidney: No significant pathology.

14, 4

DIAGNOSIS

Left renal mass, partial nephrectomy - Portion of kidney with
papillary renal cell carcinoma, Fuhrman grade 2, minimally
extending
into perirenal fat. All margins negative for tumor.

Source: NCI Genomic Data Commons file fb68cd7f-b445-4618-a552-bf588e7546f0 (TCGA-B3-3925.BFC6901A-70FE-4646-A576-5B0A27A1D0A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).